Somatic mutation profile of tumor specimen TCGA-ZN-A9VP-01A (aliquot TCGA-ZN-A9VP-01A-11D-A39R-32) from TCGA case TCGA-ZN-A9VP, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 51.2 years (18,697 days).
Specimen TCGA-ZN-A9VP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3d02abe-c2d7-46a7-b7ed-af468f5735f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZN-A9VP-10A (Blood Derived Normal), aliquot TCGA-ZN-A9VP-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b83484c0-c1d4-4e09-b593-3b7fab49be6b

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 11, Silent 6, Nonsense Mutation 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.514G>T p.V172F | Missense Mutation (SNP) | VAF 57/115 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1131691043, CM115637, COSV52672812, COSV52700410; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANKRD27 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 56/84 reads (67%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752536236; called by muse, mutect2, varscan2
- FAM234A | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs370185907; called by muse, mutect2, varscan2
- MAP2K7 | c.538G>A p.V180M | Missense Mutation (SNP) | VAF 126/367 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs746502176, COSV67608000; called by muse, mutect2, varscan2
- MAPK4 | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 93/295 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.927); catalogued as rs768923919, COSV68542758; called by muse, mutect2, varscan2
- OR4K5 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); catalogued as COSV60005099; called by muse, mutect2, varscan2
- PPP1R3B | c.838A>T p.K280* | Nonsense Mutation (SNP) | VAF 14/60 reads (23%) | catalogued as rs779843476; called by muse, mutect2, varscan2
- SLC25A37 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 179/771 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.103); catalogued as rs770182704, COSV51563529; called by muse, mutect2, varscan2
- ARID5B | c.2461del p.H821Ifs*61 | Frame Shift Del (DEL) | VAF 25/78 reads (32%) | called by mutect2, pindel, varscan2
- EFHD1 | c.124C>A p.P42T | Missense Mutation (SNP) | VAF 38/46 reads (83%) | SIFT tolerated (0.52); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- GPRC5C | c.1102G>A p.G368S (on ENST00000652232; = p.G323S on NM_018653.4) | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- LUZP1 | c.847C>T p.Q283* | Nonsense Mutation (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2
- PCARE | c.944G>T p.R315M | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- PIPOX | c.787G>T p.E263* | Nonsense Mutation (SNP) | VAF 31/80 reads (39%) | called by muse, mutect2, varscan2
- SOWAHA | c.431C>A p.T144N | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- ADARB1 | c.2139G>A p.A713= (on ENST00000360697 / NM_001346687.2; = p.A673= on NM_001112.4) | Silent (SNP) | VAF 65/199 reads (33%) | catalogued as rs768328836, COSV100653575; called by muse, mutect2, varscan2
- CHPT1 | c.234G>A p.T78= | Silent (SNP) | VAF 41/71 reads (58%) | catalogued as rs753529592, COSV57534499; called by muse, mutect2, varscan2
- GPR85 | c.501G>A p.R167= | Silent (SNP) | VAF 8/141 reads (6%) | called by muse, mutect2
- LILRB5 | c.1275C>T p.S425= | Silent (SNP) | VAF 52/135 reads (39%) | catalogued as rs907015226, COSV60259456; called by muse, mutect2, varscan2
- MEIS1 | c.129T>G p.P43= | Silent (SNP) | VAF 42/138 reads (30%) | called by muse, mutect2, varscan2
- TMEM63A | c.1428G>A p.S476= | Silent (SNP) | VAF 38/111 reads (34%) | catalogued as rs141161871; called by muse, mutect2, varscan2
